Gene-level copy-number profile of tumor specimen C3L-01277-01 from CPTAC case C3L-01277, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.2 years (22,367 days).
Specimen C3L-01277-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1d475ea-e1a9-4005-a795-0723b9124551.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01277-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/e3f13aa9-7523-422d-a5d2-6620f1c6a6ed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 49; copy number 2: 16,602; copy number 3: 14,848; copy number 4: 21,452; copy number 5: 4,185; copy number 6: 832; copy number 7: 113; copy number 8: 139; copy number 9: 19; copy number 10: 18; copy number 11: 35; copy number 12: 22; copy number 13: 4; copy number 14: 5; copy number 15: 7; copy number 16: 30; copy number 18: 1; copy number 20: 3.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr19:54,229,036–54,230,213, 1 gene (within-gene range 0–2): AC245052.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 144 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:27,638,483–27,794,005, 4 genes, copy number 10 (within-gene range 3–10): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr19:28,316,705–28,386,204, 1 gene, copy number 14: AC005580.1.
- chr19:28,883,430–29,015,160, 6 genes, copy number 10: LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr19:29,526,499–30,029,916, 11 genes, copy number 12–18 (within-gene range 4–18): VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2.
- chr19:30,850,975–30,909,155, 2 genes, copy number 11: AC011507.1, LINC01834.
- chr19:31,149,979–31,349,436, 2 genes, copy number 12 (within-gene range 7–12): TSHZ3, LINC01791.
- chr19:31,465,653–31,655,461, 5 genes, copy number 11: AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471.
- chr19:32,102,088–32,106,544, 2 genes, copy number 11: LINC01782, AC011518.1.
- chr19:32,390,050–33,175,799, 25 genes, copy number 9–20: AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88.
- chr19:33,373,685–33,815,763, 6 genes, copy number 9–16: CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15.
- chr19:34,092,561–34,093,310, 1 gene, copy number 11: RPS4XP21.
- chr19:34,172,504–34,229,515, 1 gene, copy number 11: LSM14A.
- chr19:34,994,784–35,113,664, 7 genes, copy number 9–15 (within-gene range 8–15): GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1.
- chr19:35,443,907–35,528,351, 4 genes, copy number 10: FFAR2, KRTDAP, DMKN, SBSN.
- chr19:35,704,558–35,813,299, 16 genes, copy number 11: ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2.
- chr19:36,111,151–36,173,853, 8 genes, copy number 14–15: OVOL3, POLR2I, TBCB, AD001527.2, CAPNS1, AD001527.1, COX7A1, AC002984.1.
- chr19:36,850,361–36,913,029, 1 gene, copy number 12 (within-gene range 3–12): ZNF345.
- chr19:36,888,124–36,998,700, 3 genes, copy number 12: ZNF829, RPL31P61, ZNF568.
- chr19:37,467,585–37,548,762, 4 genes, copy number 10 (within-gene range 4–10): ZNF570, ZNF793-AS1, AC022148.2, ZNF793.
- chr19:38,433,691–38,587,564, 3 genes, copy number 13: RYR1, AC067969.2, AC067969.1.
- chr19:39,125,770–39,493,785, 24 genes, copy number 16: PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50.
- chr20:50,118,254–50,315,488, 8 genes, copy number 9 (within-gene range 5–9): PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
